Somatic mutation profile of tumor specimen 5f823547-ee16-45b7-a6a0-ef25d6 (aliquot 5f823547-ee16-45b7-a6a0-ef25d6_D6) from CPTAC case 21CO006, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen 5f823547-ee16-45b7-a6a0-ef25d6: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 378d020b-8cee-49ab-8991-ba2045b93698.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 737c4705-afed-4c22-b8ef-91fa00 (Blood Derived Normal), aliquot 737c4705-afed-4c22-b8ef-91fa00_D1_2; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eaced3b3-df79-4289-8f02-48f54cc7952b

The open-access MAF lists 78 somatic variants for this specimen: 58 protein-altering or splice-affecting, 12 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 48, Silent 12, Nonsense Mutation 4, Frame Shift Del 4, Intron 3, 5'UTR 2, 3'UTR 2, Splice Site 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | hotspot (GDC flag); catalogued as rs62619935, CM992133, COSV57320867; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN11A | c.665G>A p.R222H | Missense Mutation (SNP) | VAF 17/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1230622899, CM166896, COSV56568810, COSV56574613; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 110/373 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ANKRD6 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377541073; called by muse, mutect2, varscan2
- AR | c.2511G>T p.K837N | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.986); catalogued as COSV101017520; called by muse, mutect2
- ARC | c.932C>T p.T311M | Missense Mutation (SNP) | VAF 48/542 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV63078515; called by muse, mutect2
- C2CD4C | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.327); catalogued as COSV59967582; called by muse, mutect2, varscan2
- C5orf47 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs768383117; called by muse, mutect2
- CAPN14 | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 32/224 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs777982709; called by muse, mutect2, varscan2
- CARD11 | c.3400G>A p.V1134I | Missense Mutation (SNP) | VAF 77/401 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs759681668; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL5A1 | c.3847G>A p.E1283K | Missense Mutation (SNP) | VAF 61/518 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1372225163; called by muse, mutect2, varscan2
- CYBB | c.752G>A p.W251* | Nonsense Mutation (SNP) | VAF 33/223 reads (15%) | catalogued as CM960444; called by muse, mutect2, varscan2
- DACT1 | c.2416G>A p.A806T | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs373380984; called by muse, mutect2, varscan2
- EMC1 | c.2293G>A p.V765I | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1477884906; called by muse, mutect2, varscan2
- FAM234B | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs767499682, COSV52194014; called by muse, mutect2, varscan2
- FRG2B | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.316); catalogued as COSV71042699, COSV71043031; called by muse, mutect2, varscan2
- GLI3 | c.2828C>T p.T943M | Missense Mutation (SNP) | VAF 116/380 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs778190529, COSV67893077; called by muse, mutect2, varscan2
- GLI3 | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 65/354 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.629); catalogued as COSV67889416; called by muse, mutect2, varscan2
- HSPG2 | c.10144G>A p.V3382I | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as rs147177951; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ITIH1 | c.138+1G>A p.X46_splice | Splice Site (SNP) | VAF 20/230 reads (9%) | catalogued as rs947579244, COSV56256831; called by muse, mutect2
- KIR3DL2 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs745524198, COSV99551998; called by muse, mutect2
- LCN1 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs200530565, COSV55017503; called by muse, mutect2, varscan2
- LRRTM4 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 21/223 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.953); catalogued as COSV69142029; called by muse, mutect2
- MTF1 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 29/224 reads (13%) | catalogued as COSV100888632; called by muse, mutect2, varscan2
- MYBPC3 | c.3746G>A p.G1249D | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs727504259, CM1410987; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR4C12 | c.518G>A p.G173D | Missense Mutation (SNP) | VAF 72/311 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1294043432, COSV58860648; called by muse, mutect2, varscan2
- OR52A1 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 91/355 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.052); catalogued as rs201188287, COSV61093558; called by muse, mutect2, varscan2
- OR7D2 | c.321del p.P108Lfs*8 | Frame Shift Del (DEL) | VAF 46/233 reads (20%) | catalogued as COSV100713019, COSV60139953; called by mutect2, pindel, varscan2
- PCDHA3 | c.1649C>T p.T550M | Missense Mutation (SNP) | VAF 242/870 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); catalogued as rs782401655, COSV63538552; called by muse, mutect2, varscan2
- PCSK2 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 19/170 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs142020979; called by muse, varscan2
- PIWIL2 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs772112294, COSV100769106; called by muse, mutect2, varscan2
- PIWIL3 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs139495727; called by muse, mutect2, varscan2
- PURA | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58762497; called by muse, mutect2, varscan2
- SF3B1 | c.2719G>T p.D907Y | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59205599; called by muse, mutect2, varscan2
- SLC43A1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.051); catalogued as rs201650859, COSV53558476; called by muse, mutect2, varscan2
- SMARCA4 | c.2372C>T p.A791V | Missense Mutation (SNP) | VAF 67/314 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs1263140481, COSV60786575; called by muse, mutect2, varscan2
- TPRA1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.909); catalogued as rs758345624; called by muse, mutect2, varscan2
- ZFHX4 | c.7228G>A p.A2410T | Missense Mutation (SNP) | VAF 105/273 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs770276733, COSV50588067; called by muse, mutect2, varscan2
- ZKSCAN8 | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 27/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57640623; called by muse, mutect2, varscan2
- ZNF618 | c.1037C>T p.T346M (on ENST00000374126 / NM_001318042.2; = p.T314M on NM_001318040.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/306 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs976595838; called by muse, mutect2, varscan2
- APC | c.4441_4450del p.V1481Mfs*23 | Frame Shift Del (DEL) | VAF 18/157 reads (11%) | called by mutect2, varscan2
- ATXN1L | c.1645G>A p.G549S | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC96 | c.1043G>A p.R348K | Missense Mutation (SNP) | VAF 27/208 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- CTCFL | c.1336C>A p.H446N | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDX27 | c.2369C>G p.S790C | Missense Mutation (SNP) | VAF 36/177 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- FREM3 | c.5454dup p.D1819Rfs*10 | Frame Shift Ins (INS) | VAF 28/126 reads (22%) | called by mutect2, varscan2
- HEATR1 | c.5372A>G p.K1791R | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IFT43 | c.269G>T p.S90I | Missense Mutation (SNP) | VAF 32/271 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTA3 | c.974T>C p.L325P | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- NLRP9 | c.2255del p.N752Ifs*3 | Frame Shift Del (DEL) | VAF 18/150 reads (12%) | called by mutect2, pindel, varscan2
- NOTUM | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- OR1M1 | c.312_322delinsT p.H105Afs*7 | Frame Shift Del (DEL) | VAF 30/158 reads (19%) | called by pindel, varscan2*
- PCDHGB5 | c.1534G>A p.A512T | Missense Mutation (SNP) | VAF 66/554 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PREX2 | c.4103A>G p.Y1368C | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RAB11FIP2 | c.30G>A p.W10* | Nonsense Mutation (SNP) | VAF 29/135 reads (21%) | called by muse, mutect2, varscan2
- SCGB2B2 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- TYROBP | c.97T>A p.C33S | Missense Mutation (SNP) | VAF 62/349 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- VCAM1 | c.327G>C p.Q109H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CHST1 | c.906C>T p.Y302= | Silent (SNP) | VAF 81/361 reads (22%) | called by muse, mutect2, varscan2
- CTNNA2 | c.2115C>T p.D705= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as rs758637574; called by muse, mutect2, varscan2
- GABRG3 | c.39G>A p.S13= | Silent (SNP) | VAF 19/36 reads (53%) | called by muse, mutect2, varscan2
- GBF1 | c.5031G>C p.L1677= (on ENST00000369983 / NM_001377137.1; = p.L1676= on NM_004193.3) | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as rs993308414; called by muse, mutect2
- GRK7 | c.387C>T p.A129= | Silent (SNP) | VAF 42/238 reads (18%) | catalogued as rs778988214, COSV53821439; called by muse, mutect2, varscan2
- NUP210 | c.3543G>A p.T1181= | Silent (SNP) | VAF 43/197 reads (22%) | catalogued as rs754999930; called by muse, mutect2, varscan2
- OR2G6 | c.105C>T p.Y35= | Silent (SNP) | VAF 45/204 reads (22%) | catalogued as rs772692766, COSV58574983; called by muse, mutect2, varscan2
- PCDHA13 | c.1683C>T p.N561= | Silent (SNP) | VAF 63/483 reads (13%) | catalogued as rs782324778, COSV56486193; called by muse, mutect2, varscan2
- PIK3IP1 | c.513C>T p.Y171= | Silent (SNP) | VAF 14/96 reads (15%) | catalogued as rs932778885; called by muse, mutect2, varscan2
- PURB | c.624C>T p.A208= | Silent (SNP) | VAF 28/88 reads (32%) | called by muse, mutect2, varscan2
- STARD9 | c.7992G>A p.Q2664= | Silent (SNP) | VAF 99/204 reads (49%) | called by muse, mutect2, varscan2
- VPS54 | c.1602T>C p.T534= | Silent (SNP) | VAF 47/247 reads (19%) | called by muse, mutect2, varscan2
- AAK1 | c.*1C>T | 3'UTR (SNP) | VAF 9/54 reads (17%) | called by muse, mutect2, varscan2
- ADAM6 | n.1585G>A | RNA (SNP) | VAF 26/163 reads (16%) | catalogued as rs766761084; called by muse, mutect2, varscan2
- ADSS1 | c.*4C>A | 3'UTR (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- C1orf43 | c.-12G>T | 5'UTR (SNP) | VAF 29/94 reads (31%) | called by muse, mutect2, varscan2
- IMPDH2 | c.-24A>G | 5'UTR (SNP) | VAF 36/189 reads (19%) | catalogued as rs1442955900; called by muse, mutect2, varscan2
- MPRIP | c.2163+3878A>G | Intron (SNP) | VAF 69/202 reads (34%) | called by muse, mutect2, varscan2
- RHBDF1 | c.248+273G>A | Intron (SNP) | VAF 24/128 reads (19%) | catalogued as rs780127819, COSV51953647; called by muse, mutect2, varscan2
- ZIC4 | c.-16+959C>A | Intron (SNP) | VAF 8/112 reads (7%) | called by muse, mutect2
